Somatic mutation profile of tumor specimen TCGA-K1-A42X-02A (aliquot TCGA-K1-A42X-02A-11D-A24N-09) from TCGA case TCGA-K1-A42X, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 62.1 years (22,680 days).
Specimen TCGA-K1-A42X-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bffcc553-f814-425a-97bc-ae0c3c871c3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K1-A42X-11A (Solid Tissue Normal), aliquot TCGA-K1-A42X-11A-11D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fd0957b-1801-4fec-ad17-83b0c3f3b310

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Nonsense Mutation 2, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C14orf39 | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs763379624; called by muse, mutect2, varscan2
- CD33 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51801870; called by muse, varscan2
- CSMD2 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV53917409; called by muse, mutect2, varscan2
- CYP11B2 | c.957A>G p.T319= | Splice Region (SNP) | VAF 26/72 reads (36%) | catalogued as rs1421150933; called by muse, mutect2, varscan2
- DCHS1 | c.4768G>A p.G1590S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs934539374, COSV55033450; called by muse, mutect2, varscan2
- GRM3 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.567); catalogued as rs1168442663; called by muse, mutect2, varscan2
- KANSL1 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as rs1172479780, COSV52271476; called by muse, mutect2, varscan2
- NAP1L3 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs760945470, COSV100220165, COSV59074135; called by muse, mutect2, varscan2
- NYAP2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as rs761168029, COSV56001990; called by muse, mutect2
- PLCB1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.387); catalogued as rs368967370; called by muse, mutect2, varscan2
- PPP3R2 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1291491534, COSV62457005; called by muse, mutect2, varscan2
- PTCHD3 | c.893C>A p.T298N | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs1309929543; called by muse, mutect2, varscan2
- TEKT4 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781924887; called by muse, mutect2
- WDFY2 | c.1127C>G p.A376G | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.138); catalogued as rs890733974; called by muse, mutect2, varscan2
- ARID1A | c.3236A>T p.N1079I | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ATRN | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- CIP2A | c.2259T>A p.D753E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CKAP5 | c.5074C>T p.L1692F (on ENST00000529230 / NM_001008938.4; = p.L1632F on NM_014756.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLASRP | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.22); called by muse, mutect2, varscan2
- EFHC2 | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EHBP1L1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- EHBP1L1 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- FREM1 | c.1543T>G p.L515V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GARNL3 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GRM3 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- GSDMC | c.59A>T p.D20V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HOXC5 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- KDR | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- MAP2K4 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MARK1 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO10 | c.1083A>C p.L361F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PCDHB3 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.292); called by muse, mutect2
- PRAMEF2 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PRDM2 | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- PSAT1 | c.1008-1G>C p.X336_splice (on ENST00000376588 / NM_058179.4; = p.X290_splice on NM_021154.5) | Splice Site (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- PTTG1 | c.422T>G p.L141W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB10 | c.389T>A p.M130K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TSPAN10 | c.228C>A p.D76E (on ENST00000574882 / NM_001290212.1; = p.D38E on NM_031945.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ARL4D | c.426A>G p.A142= | Silent (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- CD244 | c.30C>G p.L10= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV100458264; called by muse, mutect2, varscan2
- COL18A1 | c.3183G>A p.V1061= (on ENST00000359759 / NM_130444.3; = p.V826= on NM_030582.4) | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV60586556; called by muse, mutect2, varscan2
- KCNT2 | c.2802C>T p.D934= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as rs759501537; called by muse, mutect2, varscan2
- KRTAP19-5 | c.18C>T p.N6= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV100478434; called by muse, mutect2, varscan2
- NAV2 | c.4155C>A p.L1385= (on ENST00000396087 / NM_001244963.2; = p.L1362= on NM_145117.5) | Silent (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- PIP | c.60C>T p.C20= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV52120424; called by muse, mutect2, varscan2
- PSG7 | c.1164T>C p.H388= | Silent (SNP) | VAF 54/95 reads (57%) | called by muse, mutect2, varscan2
- PSME4 | c.1758G>A p.L586= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502140 ins TTTCC | 5'Flank (INS) | VAF 18/88 reads (20%) | called by mutect2, varscan2
